Somatic mutation profile of tumor specimen TCGA-F5-6861-01A (aliquot TCGA-F5-6861-01A-11D-1924-10) from TCGA case TCGA-F5-6861, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.1 years (21,936 days).
Specimen TCGA-F5-6861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ec5dde5-0afe-47fe-9c9f-a9609daea339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6861-10A (Blood Derived Normal), aliquot TCGA-F5-6861-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41c8e7a4-809e-4b3a-b996-ec024a919ae4

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 21, Nonsense Mutation 4, Intron 3, Splice Region 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCBP1 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by mutect2, varscan2
- ADAM12 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.367); catalogued as COSV64101808; called by muse, mutect2, varscan2
- ADAMTS2 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370013405; called by muse, mutect2, varscan2
- ADAMTS20 | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs112430320, COSV67130572, COSV67132104, COSV67137399; called by muse, mutect2, varscan2
- AKNAD1 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV62197897; called by muse, mutect2, varscan2
- ALG13 | c.2258G>A p.G753D | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.36); catalogued as COSV99323111; called by muse, mutect2, varscan2
- ANO2 | c.2426T>C p.F809S (on ENST00000356134 / NM_001278597.3; = p.F813S on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100502395; called by muse, varscan2
- ARHGEF10 | c.2641G>A p.V881I (on ENST00000398564; = p.V856I on NM_014629.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs773521162, COSV50647556; called by muse, mutect2, varscan2
- CCKAR | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as COSV55161165; called by muse, mutect2, varscan2
- CDH2 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs201148355, COSV52293905; called by mutect2, varscan2
- DCSTAMP | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1250850322, COSV52576068; called by muse, mutect2, varscan2
- DNM2 | c.2338C>T p.R780W (on ENST00000355667 / NM_001005360.3; = p.R776W on NM_004945.3) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1221582515, COSV53033683; called by muse, mutect2, varscan2
- DNM3 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs771313162, COSV62456994; called by muse, varscan2
- EEPD1 | c.1335C>G p.I445M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as rs1358460046, COSV54197723, COSV54203169, COSV99632412; called by mutect2, varscan2
- EPPK1 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV101599963, COSV73261541; called by muse, mutect2, varscan2
- FGF13 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1477376621, COSV59544138; called by muse, mutect2, varscan2
- FLG | c.6094A>T p.R2032* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV64240965; called by muse, mutect2, varscan2
- GABBR2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs566723170, COSV52301706; called by muse, mutect2, varscan2
- GPR32 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778498523, COSV54514344; called by muse, mutect2, varscan2
- HSPA4L | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV56545143; called by muse, mutect2, varscan2
- IKZF3 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53101780; called by muse, mutect2, varscan2
- INSC | c.96+1G>C p.X32_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as rs368896159, COSV65410192; called by muse, mutect2, varscan2
- ITPKC | c.1876C>G p.H626D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99649100; called by muse, mutect2, varscan2
- KCNC4 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV100873697; called by muse, mutect2, varscan2
- KIF19 | c.2299T>C p.S767P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV63429347; called by muse, mutect2, varscan2
- MAGEB10 | c.602C>G p.T201S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV100775419; called by muse, mutect2, varscan2
- MDGA1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51795351; called by muse, mutect2, varscan2
- MPP6 | c.165T>G p.N55K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV56037777; called by muse, mutect2, varscan2
- PARVG | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs768880557, COSV63561520; called by muse, mutect2, varscan2
- PDCD11 | c.3911C>T p.P1304L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs750718569, COSV63933805; called by muse, mutect2, varscan2
- PHACTR2 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.174); catalogued as COSV59854058; called by muse, mutect2, varscan2
- PKP3 | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.846); catalogued as rs775543180, COSV100520960; called by muse, mutect2, varscan2
- PLEKHG4B | c.2809G>A p.V937M (on ENST00000283426; = p.V1293M on NM_052909.5) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776584923, COSV52043730; called by muse, mutect2, varscan2
- PPFIA3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61951310; called by muse, mutect2, varscan2
- PRKCB | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281418911, COSV100335478; called by muse, mutect2, varscan2
- PRKCSH | c.1214A>G p.N405S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as rs754580626, COSV99371981; called by muse, mutect2, varscan2
- PRRT1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs1195260142, COSV52998094, COSV52999166; called by muse, mutect2, varscan2
- PRSS16 | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.604); catalogued as COSV57915385; called by muse, mutect2, varscan2
- PXDNL | c.2009A>T p.Q670L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62485829; called by muse, mutect2, varscan2
- RBMX | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV57809036; called by muse, mutect2, varscan2
- RCL1 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67754089; called by muse, mutect2, varscan2
- RELN | c.6380A>C p.Y2127S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100634974; called by muse, mutect2, varscan2
- RNF149 | c.462A>G p.G154= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99766829; called by muse, mutect2
- ROBO1 | c.4100C>T p.T1367M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV71393878; called by muse, mutect2, varscan2
- SCN11A | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201421435, COSV56566143; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDR42E1 | c.969T>G p.H323Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV61094101; called by muse, mutect2, varscan2
- SLC10A2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs765181697, COSV55358561; called by muse, mutect2, varscan2
- SLCO6A1 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs139495343, COSV65808002; called by muse, mutect2, varscan2
- SLURP1 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99872982; called by muse, mutect2, varscan2
- SMC1A | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59127901; called by muse, mutect2, varscan2
- SNAP91 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV52121128; called by muse, mutect2, varscan2
- SNED1 | c.860_868del p.D287_T290delinsA | In Frame Del (DEL) | VAF 7/26 reads (27%) | catalogued as COSV60023211; called by mutect2, pindel, varscan2
- SORCS1 | c.3264G>A p.A1088= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs752248850, COSV53861899; called by muse, mutect2, varscan2
- SYCP2L | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1438638536, COSV51652649; called by muse, mutect2, varscan2
- SYNPO | c.1582C>T p.P528S (on ENST00000394243 / NM_001166208.2; = p.P284S on NM_007286.6) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as COSV56939810; called by muse, mutect2
- TG | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs113998044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THOC2 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55544963; called by muse, mutect2, varscan2
- TJP3 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs749504969, COSV53660625; called by muse, mutect2, varscan2
- TMEM71 | c.438C>G p.N146K (on ENST00000523829 / NM_001382398.1; = p.N127K on NM_144649.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100785575, COSV63457207; called by muse, mutect2, varscan2
- TNFSF8 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV56342391; called by mutect2, varscan2
- TOP2B | c.2060C>G p.T687R (on ENST00000264331 / NM_001330700.2; = p.T682R on NM_001068.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.152); catalogued as COSV51971319; called by muse, varscan2
- TRHDE | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.436); catalogued as rs1190546035, COSV99670188, COSV99672717; called by muse, mutect2, varscan2
- TRPC7 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs1347533887, COSV100726046; called by muse, mutect2
- UTP6 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754565341, COSV55573086; called by muse, mutect2, varscan2
- UXT | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV60039380; called by muse, mutect2, varscan2
- YTHDC1 | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60010194; called by muse, mutect2, varscan2
- ZBBX | c.2268G>T p.E756D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV56788169; called by muse, mutect2, varscan2
- ZBED1 | c.1066A>T p.S356C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV58132942; called by muse, mutect2, varscan2
- ZBTB46 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1336372975, COSV55509468; called by muse, mutect2
- ZDHHC7 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs764278175, COSV58212372, COSV58213976; called by muse, mutect2, varscan2
- ZNF638 | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV52486027; called by muse, mutect2, varscan2
- IL18R1 | c.1396del p.E466Kfs*6 | Frame Shift Del (DEL) | VAF 31/136 reads (23%) | called by mutect2, pindel, varscan2
- ADARB2 | c.1935C>T p.S645= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs764627297, COSV67181799; called by muse, mutect2, varscan2
- ADCY5 | c.3213G>A p.A1071= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs111603078, COSV100567658; called by mutect2, varscan2
- BANK1 | c.426A>G p.E142= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59851095; called by muse, mutect2, varscan2
- CENPJ | c.2868A>G p.L956= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV67883368; called by muse, mutect2, varscan2
- DDX54 | c.2598C>T p.F866= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs555344760, COSV58373183; called by muse, varscan2
- ELMOD3 | c.168G>C p.L56= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV59772371, COSV59773405; called by muse, mutect2
- FBN2 | c.8085C>T p.D2695= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs765452930, COSV52497297; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIA3 | c.2400C>T p.Y800= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV52057504; called by muse, mutect2, varscan2
- GRK3 | c.393C>T p.H131= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs748162178, COSV60795409; called by muse, mutect2, varscan2
- MERTK | c.99G>A p.P33= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs771189892, COSV54928172; called by muse, mutect2, varscan2
- MRPL32 | c.414A>G p.R138= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV56239321; called by muse, mutect2, varscan2
- NYAP1 | c.2179C>T p.L727= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV55718509; called by muse, mutect2, varscan2
- PABPC5 | c.468C>T p.A156= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs770896837, COSV57040372; called by muse, mutect2, varscan2
- PODXL2 | c.75G>A p.A25= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs369628001; called by muse, mutect2, varscan2
- SIN3A | c.2493C>T p.L831= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV64582670; called by muse, mutect2, varscan2
- SLC7A14 | c.2211G>T p.A737= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV51581297; called by muse, mutect2, varscan2
- STS | c.1422C>T p.N474= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs755417956, COSV54267925; called by muse, mutect2, varscan2
- TACSTD2 | c.822C>T p.T274= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100973767; called by muse, mutect2
- TRIM23 | c.1227G>A p.T409= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs755469489, COSV51550974; called by muse, mutect2, varscan2
- UBE3C | c.1665G>T p.G555= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100780103; called by muse, mutect2, varscan2
- ZNF772 | c.714C>T p.F238= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs757759792, COSV58410696; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 3/25 reads (12%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- CRYM-AS1 | n.565T>C | RNA (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- LIM2 | c.175+28G>A | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as rs199913969, COSV55741027, COSV99702300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+683T>C | Intron (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99526752; called by muse, mutect2
